Surgical pathology report (de-identified scan), TCGA case TCGA-KQ-A41N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Cornell Medical College, specimen TCGA-KQ-A41N-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Laboratory

ical Pathology Report

Report Date:

Submitted by:

Path: 100-0-3 carcinoma, urothelial, papillary
(PCCF: urothelial, carcinoma, NOS 8130/3
Site: path: bladder, NOS 8120/3
C67.9 7-23-12
C67.0 C67.0 RD

Telephone:

Location:

CLINICAL INFORMATION:

Bladder cancer. Radical open cystoprostatectomy with ileal conduit urinary diversion.

Specimen submitted: A. Right common iliac node; B. Presacral lymph node; C. Right obturator; D. Left common iliac node; E. Left obturator; F. Distal left ureter; G. Distal right ureter; H. Left pelvic lymph node; I. Bladder, prostate seminal vesicle; J. Right pelvic lymph node

DIAGNOSIS:

A. Lymph node, right common iliac (excision):

Ten lymph nodes, negative for metastatic carcinoma (0/10).

B. Lymph node, presacral (excision):

Four lymph nodes, negative for metastatic carcinoma (0/4).

C. Lymph node, right obturator (excision):

Thirteen lymph nodes, negative for metastatic carcinoma (0/13).

D. Lymph node, left common iliac (excision):

Eighteen lymph nodes, negative for metastatic carcinoma (0/18).

E. Lymph node, left obturator (excision):

Six lymph nodes, negative for metastatic carcinoma (0/6).

F. Ureter, left "distal" (excision):

Segment of benign ureter.

G. Ureter, right "distal" (excision):

Segment of benign ureter.

H. Lymph node, left pelvic (excision):

Two lymph nodes, negative for metastatic carcinoma (0/2).

I. Bladder, prostate and seminal vesicles (radical cystoprostatectomy):

Bladder:

Invasive high-grade papillary urothelial carcinoma (2.5 cm in greatest dimension).

Tumor invades through muscularis propria into perivesical adipose tissue as a 2.5 cm extravesical mass.

No angiolymphatic invasion is identified.

[page 2 of 3]
Surgical resection margins, urethral and ureteral margins are negative for tumor.
Three lymph nodes, negative for metastatic carcinoma (0/3).
AJCC stage (7th edition): pT3b, N0.

Prostate and seminal vesicles:

Prostatic adenocarcinoma, Gleason score 4+3=7, bilateral, organ confined.

A minor component of Gleason pattern 5 is present.

A dominant tumor nodule is present in the mid region of the prostate and measures approximately 1.8 cm.

Right anterior apical margin is focally positive for tumor (block 15).

Seminal vesicles are negative for carcinoma.

AJCC stage (7th edition): pT2c, N0.

Please see staging summary.

J. Lymph node, right pelvic (excision):

One lymph node, negative for metastatic carcinoma (0/1).

PATHOLOGICAL STAGING SUMMARY:

Histologic Type:	Adenocarcinoma (conventional, not otherwise specified) Primary Pattern: Grade 4 Secondary Pattern: Grade 3 Tertiary Pattern: Grade 5 Total Gleason Score: 7
Tumor Quantitation:	Proportion (percent) of prostatic tissue involved by tumor: 15% Tumor size (dominant nodule, if present): Greatest dimension: 1.8 cm
Pathologic Staging (pTNM):	pT2c: Bilateral disease Number of regional lymph nodes examined: 57 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed
Margins:	Margin(s) involved by invasive carcinoma Unifocal margin(s) involved by invasive carcinoma Apical margin(s) involved by invasive carcinoma
Extraprostatic Extension:	Absent
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Venous (Large Vessel) Invasion (V):	Absent
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings:	High-grade prostatic intraepithelial neoplasia (PIN)

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right omentum" and consists of fibrofatty tissue measuring 4.5 x 2.5 x 0.5 cm in aggregate. 100% submitted. Summary of sections: A1 to A4-lymph node and fat.

B. Received fresh, the specimen is labeled "presacral lymph node" and consists of an aggregate of fat and lymph node measuring 5.0 x 1.5 x 0.8 cm. 100% submitted. Summary of sections: B1 to B4-lymph node and fat.

C. Received fresh, the specimen is labeled "right obturator" and consists of lymph node and fat measuring 3.5 x 2.3 x 1.3 cm in aggregate. 100% submitted. Summary of sections: C1 through C4-lymph node and fat.

D. Received fresh, the specimen is labeled "left common iliac node" and consists of lymph node and fat measuring 6.0 x 5.0 x 1.0 cm in aggregate. 100% submitted. Summary of sections: D1 through D9-lymph node and fat.

E. Received fresh, the specimen is labeled "left obturator" and consists of aggregate of lymph node and fat measuring 3.0 x 2.6 x 0.7 cm. 100% submitted. Summary of sections: E1 through E5-lymph node and fat.

[page 3 of 3]
F. Received fresh, the specimen is labeled "distal left ureter" and consists of a segment of ureter measuring 0.6 cm long and 0.6 cm in diameter with staple. Summary of sections: F1-left ureter margin.

G. Received fresh, the specimen is labeled "distal right ureter" and consists of a segment of ureter measuring 0.6 cm in length and 0.3 cm in diameter with staple. Summary of sections: G1-right ureter margin.

H. Received fresh, the specimen is labeled "right pelvic lymph node" and consists of a lymph node and fat measuring 3.0 x 2.0 x 0.6 cm. 100% of the specimen submitted. Summary of sections: H1 and H2-lymph node and fat.

I. Received fresh, the specimen is labeled "bladder prostate and seminal vesicles" and consists of a radical cytoprostectomy specimen measuring 19.5 x 13.0 x 6.0 cm overall. The prostate measures 5.0 x 4.0 x 3.5 cm. The right side of the prostate is inked green and the left inked black. Posterior wall of the urethra measures 2.5 x 0.8 cm and the bladder measures 7.0 x 6.5 x 4.5 cm. Right seminal vesicles measures 4.0 x 2.3 x 1.1 cm, left seminal vesicle measures 4.1 x 1.0 x 1.0 cm. The right vas deferens measures 12.0 x 0.5 cm and the left vas deferens measuring 4.5 x 0.4 cm, the right ureter measures 8.0 x 0.5 cm and left ureter measures 5.0 x 1.0 cm. There is 5.0 x 4.0 x 3.0 cm polypoid mass at the left ureter orifice. Upon opening the bladder and prostate anteriorly, there is a 2.5 x 2.0 x 2.0 cm ill-defined firm white tan mass in the left bladder wall which invades up to the edge of muscularis propria. There is also 2.2 x 2.0 x 2.0 cm mass in the left anterior prostate and the mass is also seen invading the right part of the prostate. Representative sections of the tumor, the prostate and the bladder are submitted. Summary of sections: I1-right ureter margin, I2-left ureter margin, I3-posterior distal urethral margin, I4-urethra closer to prostate, I5-RA apex, I6-RP apex, I7-LA apex, I8-LP apex, I9-RAA, I10-RPA, I11-LAA, I12-LPA, I13-RAB, I14-RPB, I15-LAB, I16-LPB, I17-RAC, I18-RPC, I19-LAC, I20-LPC, I21-prostatic tumor to periprostatic fat, I22-prostatic tumor to inked margin, I23-prostatic tumor to periprostatic fat, I24-prostatic tumor to inked margin, I25-RSV, I26-LSV, I27-representative of the polypoid mass, I28-prostate to bladder, mid, I29-prostate to bladder right, I30 and I31-prostate to bladder and tumor, left, I32 and I33-bladder tumor closest to muscularis propria and fat at left lateral wall, I34 and I35-tumor to bladder left lateral wall, I36-tumor to bladder left lateral wall, I37-representative of the pedunculated wall, I38-bladder right lateral wall, I39-posterior wall, I40-bladder dome, I41-lymph node bisected, I42-lymph node bisected, I43-lymph node bisected, I44 through I46-fat, I47 through I53, additional sections. (

*** Electronically Signed Out ***

Attending Pathologist

The attending pathologist whose signature appears on this report has reviewed the diagnostic slides, and has edited the gross and microscopic portions of the report in rendering the final diagnosis.

Slides: A-4, B-4, C-4, D-9, E-5, F-1, G-1, H-2, I-46, J-3

Source: NCI Genomic Data Commons file cadc92b6-425d-4caf-9bd1-fac62fceed28 (TCGA-KQ-A41N.3C2A6E9E-9C14-40F5-BD61-7BF5FF26ECC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).